Somatic mutation profile of tumor specimen 0DRL0Z from CCDI case PBCGMP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 11.8 years (4,318 days).
Specimen 0DRL0Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8363f8bc-d16c-4e1b-851b-beb696d1d530.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRL1N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd1f7c0-e61d-4e4a-913a-f39331f26395

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SUN5 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 49/787 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1230619814, COSV50068477; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 64/1950 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- GRM6 | c.1262C>A p.A421E | Missense Mutation (SNP) | VAF 366/871 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- IQCN | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 155/1335 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMLHE | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 168/877 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- L1CAM | c.2715C>T p.P905= | Silent (SNP) | VAF 374/386 reads (97%) | catalogued as rs782031914; called by muse, mutect2, varscan2
- PDE4D | c.456-214415G>A | Intron (SNP) | VAF 143/1232 reads (12%) | called by muse, mutect2, varscan2
- RASGRF2 | c.544-82C>T | Intron (SNP) | VAF 147/351 reads (42%) | called by muse, mutect2, varscan2
- TNK1 | c.235-9C>T | Intron (SNP) | VAF 256/995 reads (26%) | called by muse, mutect2, varscan2
